FM case AD11804 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/d22c2b77-c280-48a8-9104-04cd452a2a6f

Male, 47.2 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the bone. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Tumor.
